Gene-level copy-number profile of specimen HCM-SANG-1315-C18-85A-01D-A80T-32 from HCMI case HCM-SANG-1315-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-1315-C18-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 17fab0fa-c5dc-4d0f-8e6f-d5a259809278.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-1315-C18-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,226 have no estimate.
https://portal.gdc.cancer.gov/files/85afd439-81d4-4336-ab1e-758c38425042

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 1,247; copy number 3: 31; copy number 4: 24,684; copy number 5: 10,551; copy number 6: 15,401; copy number 7: 1,518; copy number 8: 2,707; copy number 9: 702; copy number 10: 1,395; copy number 11: 161.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,095 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:35,860,249–35,861,498, 1 gene, copy number 9: KRT18P14.
- chr11:48,945,694–49,038,451, 6 genes, copy number 9: TRIM51CP, AC027369.2, TRIM51GP, TRIM53CP, AC027369.1, TRIM49B.
- chr11:50,170,156–50,208,794, 2 genes, copy number 9: AC109635.3, AC109635.6.
- chr11:50,409,042–50,422,316, 1 gene, copy number 9: AC024405.1.
- chr11:54,657,120–54,693,359, 6 genes, copy number 9: OR4R2P, OR4A4P, OR4A3P, OR4A2P, OR4A8, OR4A7P.
- chr12:12,310–27,325,959, 684 genes, copy number 9 (broad region; genes not listed).
- chr20:87,250–16,053,197, 288 genes, copy number 10 (within-gene range 4–10) (broad region; genes not listed).
- chr20:15,892,355–64,327,972, 1,107 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
